Somatic mutation profile of cancer-model specimen HCM-CSHL-0699-C56-85B (3D Organoid, passage 3; aliquot HCM-CSHL-0699-C56-85B-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0699-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Ovary.
Specimen HCM-CSHL-0699-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36c8c415-e0e7-4b64-ae29-f0863370f610.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0699-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0699-C56-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbbf1b06-44f9-4177-96bb-8ebde97bb8d2

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 18, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 338/666 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CACNA1H | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 45/1009 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763744269; called by muse, mutect2
- MARCHF1 | c.310C>T p.R104C (on ENST00000274056; = p.R87C on NM_017923.4) | Missense Mutation (SNP) | VAF 269/271 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs146337383; called by muse, mutect2, varscan2
- OR2W3 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 433/433 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753135293, COSV64456550, COSV64458077; called by muse, mutect2, varscan2
- PRPF40B | c.2014C>T p.R672W (on ENST00000380281; = p.R659W on NM_012272.3) | Missense Mutation (SNP) | VAF 191/422 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755027407, COSV53302812; called by muse, mutect2, varscan2
- PRR23B | c.409G>T p.V137F | Missense Mutation (SNP) | VAF 274/576 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV100271887; called by muse, mutect2, varscan2
- PTPRQ | c.6122C>T p.S2041L (on ENST00000616559; = p.S2008L on NM_001145026.2) | Missense Mutation (SNP) | VAF 115/256 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs533166022, COSV57038362; called by muse, mutect2, varscan2
- UCHL3 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 112/112 reads (100%) | catalogued as rs767343926; called by muse, mutect2, varscan2
- FBN2 | c.8398G>A p.D2800N | Missense Mutation (SNP) | VAF 227/429 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- GRM6 | c.1627T>A p.C543S | Missense Mutation (SNP) | VAF 452/896 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- KCNH1 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 91/91 reads (100%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGEB18 | c.414C>G p.I138M | Missense Mutation (SNP) | VAF 274/537 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- MED12 | c.4100T>A p.I1367N | Missense Mutation (SNP) | VAF 332/636 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MXRA5 | c.545T>A p.L182H | Missense Mutation (SNP) | VAF 413/850 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- PWWP3B | c.1627G>T p.D543Y | Missense Mutation (SNP) | VAF 466/919 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPGR | c.2815A>T p.S939C (on ENST00000339363 / NM_001367249.1; = p.S734C on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/368 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.339); called by muse, mutect2
- SH3BP4 | c.1662G>T p.E554D | Missense Mutation (SNP) | VAF 266/619 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WRAP73 | c.233T>C p.L78S | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ZNF595 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 37/287 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ARID1A | c.819C>A p.A273= | Silent (SNP) | VAF 548/556 reads (99%) | called by muse, mutect2, varscan2
- ATP8B1 | c.3033G>A p.L1011= | Silent (SNP) | VAF 116/116 reads (100%) | catalogued as rs745812626; called by muse, mutect2, varscan2
- MYBL2 | c.141G>A p.R47= | Silent (SNP) | VAF 293/640 reads (46%) | called by muse, mutect2
- SLC2A3 | c.520C>T p.L174= | Silent (SNP) | VAF 126/276 reads (46%) | called by muse, mutect2, varscan2
- TCF7L1 | c.1680G>A p.P560= | Silent (SNP) | VAF 423/888 reads (48%) | catalogued as rs143744812; called by muse, mutect2, varscan2
- TNKS2 | c.1038A>T p.R346= | Silent (SNP) | VAF 252/540 reads (47%) | called by muse, mutect2, varscan2
